Somatic mutation profile of tumor specimen TCGA-H4-A2HO-01A (aliquot TCGA-H4-A2HO-01A-11D-A17V-08) from TCGA case TCGA-H4-A2HO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 53.7 years (19,630 days).
Specimen TCGA-H4-A2HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a12fe5d-7ec6-47e1-b380-332cdadd07dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H4-A2HO-10A (Blood Derived Normal), aliquot TCGA-H4-A2HO-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0e4f894-849e-4562-849b-4bdf1c37a385

The open-access MAF lists 106 somatic variants for this specimen: 78 protein-altering or splice-affecting, 28 silent.
By variant classification: Missense Mutation 61, Silent 28, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4903C>G p.Q1635E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV67133368; called by muse, mutect2, varscan2
- ADAMTS20 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67133377; called by mutect2, varscan2
- BANP | c.1344+1G>T p.X448_splice (on ENST00000286122; = p.X420_splice on NM_079837.3) | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV53739045; called by muse, varscan2
- BOLL | c.652T>A p.Y218N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV56574899; called by muse, mutect2, varscan2
- C11orf53 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV54721890; called by muse, mutect2, varscan2
- CACNA2D2 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758052476, COSV56564926; called by mutect2, varscan2
- CCDC102B | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV60136073, COSV60144997; called by mutect2, varscan2
- CCDC63 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs536653873, COSV57528815; called by mutect2, varscan2
- CDKN2B | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.218); catalogued as COSV52805148; called by muse, mutect2, varscan2
- CFC1 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV99383473; called by muse, varscan2
- CNR2 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as COSV100991577, COSV65693271; called by muse, mutect2, varscan2
- COL6A5 | c.6085G>C p.E2029Q (on ENST00000312481; = p.E2025Q on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372956740; called by muse, mutect2, varscan2
- CYP4F12 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV61174396; called by muse, mutect2, varscan2
- DBN1 | c.1751A>G p.E584G | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52790219; called by muse, mutect2, varscan2
- DNAH5 | c.7015G>A p.G2339S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54232509; called by muse, mutect2, varscan2
- DOCK4 | c.3513G>A p.M1171I | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV69854814; called by muse, mutect2, varscan2
- DST | c.9698T>G p.L3233R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV55021295; called by muse, mutect2, varscan2
- EFCAB13 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV58949518; called by muse, mutect2, varscan2
- EFNB1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as CD084084, COSV52661992; called by muse, mutect2, varscan2
- FCER1A | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs374481114, COSV63668688; called by mutect2, varscan2
- GYS2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1409001505, COSV53924583, COSV53929660; called by muse, mutect2, varscan2
- H2BC8 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.031); catalogued as rs1310677113, COSV55126280; called by muse, mutect2, varscan2
- HFM1 | c.3313A>G p.T1105A | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54029639; called by muse, mutect2, varscan2
- HIVEP1 | c.4501A>C p.T1501P | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV65102536; called by muse, mutect2, varscan2
- HLA-C | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs281860364, COSV66113918; called by muse, mutect2, varscan2
- INTS4 | c.2255A>C p.E752A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV59019169; called by muse, mutect2, varscan2
- KIAA1217 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56818228; called by muse, mutect2, varscan2
- KIF26A | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs773032783, COSV59465897; called by mutect2, varscan2
- LONRF3 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 24/30 reads (80%) | catalogued as COSV59151153; called by muse, mutect2, varscan2
- LRRC49 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV53011770; called by muse, mutect2, varscan2
- MAFB | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV64826771; called by muse, mutect2, varscan2
- MAST3 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752460522, COSV53217327, COSV99445757; called by muse, mutect2, varscan2
- MCMDC2 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1316573771, COSV58037011; called by muse, mutect2, varscan2
- MTERF4 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as COSV54089548; called by muse, mutect2, varscan2
- MTREX | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV57926885; called by muse, mutect2, varscan2
- MYBBP1A | c.3169G>T p.G1057C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV54598858; called by mutect2, varscan2
- MYLK3 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV67364858; called by mutect2, varscan2
- NBAS | c.558G>C p.L186F | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55725600; called by muse, mutect2, varscan2
- NUAK2 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as rs777411761; called by mutect2, varscan2
- PAPOLG | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV53183321; called by muse, mutect2, varscan2
- PARD3 | c.1959G>C p.K653N | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV60752443; called by muse, mutect2, varscan2
- PCDHA7 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV65342050; called by muse, mutect2, varscan2
- PCDHGB6 | c.140T>A p.V47E | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53967631; called by muse, mutect2, varscan2
- PLA2G4C | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV62785971; called by muse, mutect2, varscan2
- PLCH2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV53944983; called by muse, mutect2, varscan2
- PPFIA2 | c.2816T>C p.I939T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61036890; called by muse, mutect2, varscan2
- RC3H1 | c.3319C>G p.L1107V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV51203438; called by muse, mutect2, varscan2
- RETREG2 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as COSV56087868; called by muse, mutect2, varscan2
- SLC6A14 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV64147456; called by muse, mutect2, varscan2
- SNAI3 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758761106, COSV60002963; called by muse, mutect2, varscan2
- SNX6 | c.1164T>A p.N388K (on ENST00000652385; = p.N260K on NM_021249.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61918796; called by muse, mutect2, varscan2
- SPTBN2 | c.2836C>A p.L946M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.897); catalogued as COSV59454187; called by mutect2, varscan2
- SRCIN1 | c.3206C>T p.S1069L (on ENST00000621492; = p.S1035L on NM_025248.3) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1299457759; called by muse, mutect2, varscan2
- SSPOP | n.13429_13432+21del | Splice Site (DEL) | VAF 31/101 reads (31%) | catalogued as COSV65131854; called by mutect2, pindel
- STXBP1 | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64813626; called by muse, mutect2, varscan2
- TGS1 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs749884409, COSV52700812; called by muse, mutect2, varscan2
- TLL1 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.034); catalogued as COSV50293109, COSV50339804; called by muse, varscan2
- TMEM198 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54721885; called by muse, mutect2
- TMEM214 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.124); catalogued as COSV53193021; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3109G>C p.D1037H | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV64101430; called by muse, mutect2, varscan2
- UMODL1 | c.1286_1299+20del p.X429_splice | Splice Site (DEL) | VAF 51/182 reads (28%) | catalogued as COSV61160623; called by mutect2, pindel
- ZKSCAN7 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs370899432; called by muse, mutect2, varscan2
- ZNF343 | c.1316G>T p.C439F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1417201275, COSV53854335; called by muse, mutect2, varscan2
- ZNF569 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 33/109 reads (30%) | catalogued as COSV57593771; called by muse, mutect2, varscan2
- ARID1A | c.5080del p.L1694Cfs*9 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- ASPN | c.1068C>A p.Y356* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- CAVIN1 | c.929_930del p.R310Lfs*114 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by pindel, varscan2
- CNTNAP4 | c.546del p.V183Wfs*19 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- DLGAP4 | c.1163C>A p.S388* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- HACE1 | c.1589G>A p.W530* | Nonsense Mutation (SNP) | VAF 51/158 reads (32%) | called by muse, mutect2, varscan2
- MUC16 | c.38302G>C p.D12768H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.37837G>C p.D12613H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRR30 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- QPCT | c.731dup p.L244Ffs*32 | Frame Shift Ins (INS) | VAF 26/95 reads (27%) | called by mutect2, pindel, varscan2
- STON1-GTF2A1L | c.2506del p.L836Ffs*10 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- TLE4 | c.406del p.Q136Sfs*13 | Frame Shift Del (DEL) | VAF 59/235 reads (25%) | called by mutect2, pindel, varscan2
- ABRAXAS2 | c.1071C>T p.D357= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV53717382; called by muse, mutect2, varscan2
- ATE1 | c.75C>T p.Y25= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1193071304, COSV56437633; called by muse, mutect2, varscan2
- BOC | c.2106G>A p.S702= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as rs750113090, COSV56349732, COSV56355797; called by muse, mutect2, varscan2
- CCDC191 | c.666G>A p.S222= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs769901640, COSV55673031; called by muse, mutect2, varscan2
- COL5A3 | c.591C>T p.F197= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs930188997, COSV53407189; called by muse, mutect2, varscan2
- CREB5 | c.708G>A p.L236= (on ENST00000357727 / NM_182898.4; = p.L229= on NM_004904.3) | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV63222482; called by muse, mutect2, varscan2
- EDN3 | c.27C>T p.F9= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1025563360, COSV61108424; called by muse, mutect2, varscan2
- EIF2AK3 | c.624T>C p.Y208= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV57548701; called by muse, mutect2, varscan2
- EPHA7 | c.2799A>G p.Q933= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV65185051; called by muse, mutect2, varscan2
- FAM89A | c.468C>T p.H156= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as rs141662238; called by muse, mutect2, varscan2
- FGA | c.1761G>C p.T587= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV57397294, COSV57400755; called by muse, mutect2, varscan2
- FJX1 | c.813C>T p.A271= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs760901534; called by mutect2, varscan2
- HAP1 | c.1473C>T p.L491= (on ENST00000310778 / NM_001367460.1; = p.L439= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV57878838; called by mutect2, varscan2
- HIF1AN | c.399G>A p.Q133= | Silent (SNP) | VAF 43/170 reads (25%) | catalogued as COSV54500759; called by muse, mutect2, varscan2
- HSPA1A | c.1686C>T p.I562= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV65149150; called by muse, mutect2, varscan2
- IQSEC2 | c.1350T>C p.S450= (on ENST00000642864 / NM_001111125.3; = p.S245= on NM_015075.2) | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV64726202; called by muse, mutect2, varscan2
- KLHL8 | c.1023C>T p.I341= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV56748224; called by muse, mutect2, varscan2
- MAP7D1 | c.246G>A p.P82= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs200123517; called by mutect2, varscan2
- MATN3 | c.903G>A p.K301= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs200161462, COSV68100026; called by muse, mutect2, varscan2
- MTHFD1 | c.2682C>T p.S894= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as rs565206627, COSV53701152; called by mutect2, varscan2
- NUMBL | c.333A>G p.R111= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV53284278, COSV53285823; called by muse, mutect2, varscan2
- OBSCN | c.3618G>A p.L1206= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV52785348; called by muse, mutect2, varscan2
- OR5R1 | c.645C>A p.L215= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV56572634; called by muse, mutect2, varscan2
- PCDHA7 | c.1854G>C p.A618= | Silent (SNP) | VAF 45/149 reads (30%) | catalogued as rs782452035, COSV65343853, COSV65344941; called by muse, mutect2, varscan2
- PIKFYVE | c.2355A>T p.R785= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV52243190; called by mutect2, varscan2
- PLEKHG7 | c.1446G>A p.V482= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV60821978; called by muse, varscan2
- PSTK | c.9C>T p.T3= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs753095831, COSV64398667; called by muse, mutect2, varscan2
- SLC13A2 | c.1146C>T p.F382= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs1555604154, COSV100120328, COSV58995016; called by muse, varscan2
